Somatic mutation profile of tumor specimen TCGA-2J-AAB6-01A (aliquot TCGA-2J-AAB6-01A-11D-A40W-08) from TCGA case TCGA-2J-AAB6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,600 days).
Specimen TCGA-2J-AAB6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 643ec18c-131a-4c9f-95e4-bb235723691d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AAB6-10A (Blood Derived Normal), aliquot TCGA-2J-AAB6-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/420f7315-4ca3-432c-a958-9ccc88e7e2d5

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 6, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 116/220 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 53/112 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AQP4 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs374302276; called by muse, mutect2, varscan2
- CACNA1F | c.5173C>G p.L1725V | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100545285; called by muse, mutect2, varscan2
- CCDC105 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 39/162 reads (24%) | catalogued as rs372493151; called by muse, mutect2, varscan2
- CDC25A | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 559/1273 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs1020851978, COSV100207633; called by muse, mutect2, varscan2
- CENPJ | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 97/538 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs769000518, COSV67883049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOXA2 | c.937T>G p.L313V | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as COSV99973456; called by muse, mutect2, varscan2
- EFCAB6 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 147/572 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as rs750787529, COSV53073328; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 235/456 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs780759837, COSV100348982; called by muse, mutect2, varscan2
- ETS1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV100091241; called by muse, mutect2, varscan2
- FPR1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 275/582 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1192119303, COSV59051081; called by muse, mutect2, varscan2
- FSHR | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58623618, COSV58624141; called by muse, mutect2, varscan2
- GGCX | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 155/512 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs765524930, COSV99290143; called by muse, mutect2, varscan2
- GPR26 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99501047; called by muse, mutect2, varscan2
- HYDIN | c.13724G>T p.S4575I | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV101125194; called by muse, mutect2, varscan2
- IGF2R | c.5692G>A p.D1898N | Missense Mutation (SNP) | VAF 130/488 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs754114803, COSV100808022; called by muse, mutect2, varscan2
- KCNG3 | c.1221T>A p.F407L | Missense Mutation (SNP) | VAF 140/446 reads (31%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.987); catalogued as COSV100045371; called by muse, mutect2, varscan2
- KIF1A | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242076; called by muse, mutect2, varscan2
- KSR2 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs772671793, COSV56677726; called by muse, mutect2, varscan2
- LCE2C | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 206/1152 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV100909469; called by muse, mutect2, varscan2
- LMF2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); catalogued as rs144342127; called by muse, mutect2, varscan2
- MS4A1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 57/267 reads (21%) | catalogued as COSV100619414; called by muse, mutect2, varscan2
- MYL9 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 126/340 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54072247; called by muse, mutect2, varscan2
- NPHS2 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 408/1012 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV100858202; called by muse, mutect2, varscan2
- NTNG2 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 87/261 reads (33%) | catalogued as COSV62365842; called by muse, mutect2, varscan2
- OR2L2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 93/438 reads (21%) | catalogued as rs546778867, COSV63547603; called by muse, mutect2, varscan2
- OR4F6 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); catalogued as rs1467865541, COSV100186976; called by muse, mutect2, varscan2
- PCDH9 | c.3652A>T p.N1218Y (on ENST00000377865 / NM_203487.3; = p.N1184Y on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV100122794; called by muse, mutect2, varscan2
- PCNX1 | c.3599T>G p.I1200S | Missense Mutation (SNP) | VAF 93/436 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99456874; called by muse, mutect2, varscan2
- PIF1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99165161; called by muse, varscan2
- PLEKHA4 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 201/362 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1449090066, COSV99613037; called by muse, mutect2, varscan2
- POTEE | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 138/649 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs777240667, COSV58225008; called by muse, mutect2, varscan2
- PTPN13 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.114); catalogued as COSV57419112; called by muse, mutect2, varscan2
- PXK | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100244379, COSV57086339, COSV57087332; called by muse, mutect2, varscan2
- SEMA3A | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.099); catalogued as COSV99547722; called by muse, mutect2, varscan2
- SESTD1 | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100090818; called by muse, mutect2, varscan2
- SGSM1 | c.2264A>G p.N755S (on ENST00000400359 / NM_001039948.4; = p.N694S on NM_133454.3) | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.449); catalogued as rs373981289; called by muse, mutect2, varscan2
- SH3TC2 | c.284T>A p.L95H | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100102243; called by muse, mutect2, varscan2
- SP140 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.249); catalogued as rs201685101, COSV59448691; called by muse, mutect2, varscan2
- TENM4 | c.3245C>T p.P1082L | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs764922741, COSV53657920; called by muse, mutect2, varscan2
- TMEM198 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs201245165, COSV99705241; called by muse, mutect2, varscan2
- TTN | c.55549G>A p.G18517S (on ENST00000591111; = p.G11093S on NM_003319.4) | Missense Mutation (SNP) | VAF 215/850 reads (25%) | PolyPhen probably damaging (0.999); catalogued as rs375009570, COSV100625963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF365 | c.307A>T p.S103C | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs753431261, COSV101237980; called by muse, mutect2, varscan2
- ZNF500 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs142409847; called by muse, mutect2, varscan2
- ZNF554 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 126/437 reads (29%) | catalogued as rs1217258814, COSV100421292; called by muse, mutect2, varscan2
- ZSCAN21 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 111/443 reads (25%) | catalogued as rs747883825, COSV52850529; called by muse, mutect2, varscan2
- C5 | c.1026dup p.P343Tfs*34 | Frame Shift Ins (INS) | VAF 150/366 reads (41%) | called by mutect2, pindel, varscan2
- DNM1L | c.328_330del p.E110del | In Frame Del (DEL) | VAF 69/161 reads (43%) | called by mutect2, pindel, varscan2
- AJAP1 | c.216G>A p.A72= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs745464898, COSV100981973; called by muse, mutect2, varscan2
- ASPM | c.559A>C p.R187= | Silent (SNP) | VAF 171/436 reads (39%) | catalogued as COSV99660944; called by muse, mutect2, varscan2
- CFAP47 | c.4377T>C p.A1459= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as rs1430393317, COSV100545642; called by muse, mutect2, varscan2
- GRIK4 | c.1422C>T p.G474= | Silent (SNP) | VAF 270/680 reads (40%) | catalogued as rs144767530, COSV70803287; called by muse, mutect2, varscan2
- ITGB2 | c.2280G>A p.R760= (on ENST00000302347; = p.R736= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/282 reads (27%) | catalogued as COSV100186085; called by muse, mutect2, varscan2
- MYT1L | c.2430C>T p.G810= | Silent (SNP) | VAF 84/313 reads (27%) | catalogued as COSV67706698; called by muse, mutect2, varscan2
- OR14A16 | c.330G>T p.L110= | Silent (SNP) | VAF 73/385 reads (19%) | catalogued as COSV100713845, COSV62927434; called by muse, mutect2, varscan2
- OR2L8 | c.784A>C p.R262= | Silent (SNP) | VAF 94/446 reads (21%) | catalogued as COSV100594295, COSV61726079; called by muse, mutect2, varscan2
- PITPNM1 | c.2427C>T p.A809= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99653792; called by muse, mutect2
- PKD1L1 | c.603G>A p.A201= | Silent (SNP) | VAF 53/349 reads (15%) | catalogued as rs141425680; called by muse, mutect2, varscan2
- RSPH10B | c.165G>A p.V55= | Silent (SNP) | VAF 83/487 reads (17%) | catalogued as COSV61755414; called by muse, mutect2, varscan2
- RSPH6A | c.1422G>A p.P474= | Silent (SNP) | VAF 56/415 reads (13%) | catalogued as rs747375944, COSV99680061; called by muse, mutect2, varscan2
- SALL2 | c.2274G>A p.P758= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as rs200356033; called by muse, mutect2, varscan2
- ZNF99 | c.1803T>C p.A601= | Silent (SNP) | VAF 80/277 reads (29%) | catalogued as COSV101233920; called by muse, mutect2, varscan2
- GRIA4 | c.2295-5891G>A | Intron (SNP) | VAF 80/202 reads (40%) | catalogued as rs774816694, COSV56882997; called by muse, mutect2, varscan2
